Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4790, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4790-01A (Primary Tumor).

[page 1 of 2]
Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

h right renal mass.

Specimens Submitted:

1: SP: Kidney, right, partial nephrectomy

DIAGNOSIS:

1. SP: Kidney, right, partial nephrectomy

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 3.5 cm.

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

N/A

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Mild focal chronic interstitial inflammation

Adrenal Gland:

N/A

Lymph Nodes:

N/A

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

Comment: The tumor is associated with a granulomatous response

[page 2 of 2]
Gross Description:

1.) The specimen is received fresh for frozen section, labeled "right renal tumor stitch marks deep margin" and consists of a portion of kidney with attached perinephric fat measuring 4.5 x 4.3 x 4.0 cm. The specimen is serially sectioned, revealing a golden yellow tumor with areas of hemorrhage measuring 3.5 x 3.0 x 2.8 cm. The tumor grossly does not extend into the perinephric fat and is located 0.1cm away from the inked black resection margin. Representative sections are submitted for frozen and paraffin sections.

Summary of sections:

FSC -- frozen section control

M -- margin

T -- tumor

N -- uninvolved kidney

Summary of Sections:

Part 1: SP: Kidney, right, partial nephrectomy

Block	Sect. Site	PCs
1	FSC	1
1	M	1
1	N	1
2	T	2

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the Intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL NEOPLASM, DEEP MARGIN IS NEGATIVE.
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file c45a8beb-8d16-4173-ad84-63b6aa415ffc (TCGA-BP-4790.844E4351-1926-4510-B766-E203D3F8BE50.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).